Somatic mutation profile of tumor specimen TCGA-DD-AAE7-01A (aliquot TCGA-DD-AAE7-01A-11D-A40R-10) from TCGA case TCGA-DD-AAE7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 72.7 years (26,568 days).
Specimen TCGA-DD-AAE7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc635350-337a-428e-b64c-f1f61327216d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAE7-10A (Blood Derived Normal), aliquot TCGA-DD-AAE7-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9eaee38-a0d1-4f16-b54c-cd8e25a03401

The open-access MAF lists 277 somatic variants for this specimen: 207 protein-altering or splice-affecting, 61 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 61, Frame Shift Del 13, Nonsense Mutation 12, Intron 7, Splice Site 6, In Frame Del 3, Splice Region 2, In Frame Ins 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC126283.2 | c.260A>C p.Q87P | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV101144514; called by muse, mutect2, varscan2
- ADIPOQ | c.576T>A p.N192K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV100292186; called by muse, mutect2, varscan2
- AGFG2 | c.401T>C p.F134S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99499381; called by muse, mutect2, varscan2
- AK9 | c.3229C>A p.P1077T | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as COSV100393922, COSV58150941; called by muse, mutect2, varscan2
- AKIRIN2 | c.470A>C p.K157T | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV100005235; called by muse, mutect2, varscan2
- AL645922.1 | c.2489A>T p.D830V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.156); catalogued as COSV100191191; called by muse, mutect2, varscan2
- AP3B1 | c.1853A>G p.Q618R | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV99671715; called by muse, mutect2, varscan2
- APBB3 | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs1404667500, COSV100021349; called by muse, mutect2, varscan2
- ARHGEF15 | c.2498C>T p.S833L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100730061; called by muse, mutect2, varscan2
- ARID1A | c.4495C>T p.Q1499* | Nonsense Mutation (SNP) | VAF 5/97 reads (5%) | catalogued as COSV100252060; called by muse, mutect2
- ASGR1 | c.599T>G p.F200C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52649228; called by muse, mutect2, varscan2
- BACE2 | c.1079T>C p.I360T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100160883; called by muse, mutect2, varscan2
- BCAS1 | c.48T>A p.N16K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV101006268; called by muse, mutect2, varscan2
- BEND4 | c.1445A>G p.Q482R | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1369985790, COSV101549759; called by muse, mutect2, varscan2
- BLOC1S2 | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100705069; called by muse, mutect2
- BRSK1 | c.317T>A p.L106* | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100510669; called by muse, mutect2, varscan2
- CASS4 | c.1348A>T p.K450* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100824749; called by muse, mutect2, varscan2
- CBWD1 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 24/299 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100071013; called by muse, mutect2
- CCDC33 | c.370T>A p.Y124N | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV100351482; called by muse, mutect2, varscan2
- CCDC71 | c.785C>G p.T262S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV100422376; called by muse, mutect2, varscan2
- CCNC | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as rs1201923177, COSV100412619; called by muse, mutect2, varscan2
- CCNF | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99563763; called by muse, mutect2, varscan2
- CCS | c.373G>T p.G125W | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100040035; called by muse, mutect2, varscan2
- CDC20B | c.218T>G p.I73S | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV99697020; called by muse, mutect2, varscan2
- CDHR2 | c.3562A>G p.M1188V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99991745; called by muse, mutect2, varscan2
- CEACAM3 | c.149A>T p.E50V | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99705004; called by muse, mutect2, varscan2
- CENPF | c.1503A>C p.E501D | Missense Mutation (SNP) | VAF 27/573 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as COSV100871730; called by muse, mutect2
- CEP68 | c.977A>T p.D326V | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99561009; called by muse, mutect2, varscan2
- CFAP300 | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101462466; called by muse, mutect2, varscan2
- CFAP47 | c.2069T>A p.L690Q | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as COSV99935282; called by muse, mutect2, varscan2
- CHD9 | c.6625A>T p.T2209S | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.52); catalogued as COSV99529277; called by muse, mutect2, varscan2
- CHPF | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV99705044; called by muse, mutect2, varscan2
- CHRM1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV100186214; called by muse, mutect2, varscan2
- CILP2 | c.1660A>T p.M554L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99364813; called by muse, mutect2, varscan2
- CLEC12A | c.92-2A>T p.X31_splice | Splice Site (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100429538; called by muse, mutect2, varscan2
- COG3 | c.1223A>T p.D408V | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100596575; called by muse, mutect2, varscan2
- COG3 | c.2372A>G p.Q791R | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as rs990065757, COSV100596577; called by muse, mutect2
- COMMD3-BMI1 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100936420; called by muse, mutect2, varscan2
- COPG1 | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs369091902; called by muse, mutect2, varscan2
- COX6B1 | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1309733580, COSV99876908; called by muse, mutect2, varscan2
- CSF1 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV100294601, COSV60032493; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1733A>C p.N578T | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99600061; called by muse, mutect2, varscan2
- DCAF10 | c.442A>G p.M148V | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99647755; called by muse, mutect2, varscan2
- DENND4A | c.4604C>T p.S1535F | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as COSV101475366; called by muse, mutect2, varscan2
- DEUP1 | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 109/354 reads (31%) | catalogued as COSV53216661, COSV99977254; called by muse, mutect2, varscan2
- DGKA | c.2056A>G p.T686A | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs1472954760, COSV100093152; called by muse, mutect2, varscan2
- DHX36 | c.1010A>G p.H337R | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100273675; called by muse, mutect2
- DIPK2B | c.1204del p.A402Pfs*5 | Frame Shift Del (DEL) | VAF 49/87 reads (56%) | catalogued as COSV67641668; called by mutect2, pindel, varscan2
- DLG1 | c.43T>G p.L15V | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100015482; called by muse, mutect2, varscan2
- DMD | c.9125A>C p.H3042P | Missense Mutation (SNP) | VAF 149/231 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100627749; called by muse, mutect2, varscan2
- DOCK7 | c.5749G>A p.E1917K (on ENST00000635253 / NM_001367561.1; = p.E1886K on NM_033407.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557597200, COSV99224837; called by muse, mutect2, varscan2
- DST | c.16069A>G p.T5357A (on ENST00000361203 / NM_001374722.1; = p.T2945A on NM_015548.5) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.075); catalogued as COSV99757331; called by muse, mutect2, varscan2
- DVL3 | c.930G>C p.M310I | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1414366674, COSV100493698; called by muse, mutect2
- EDEM3 | c.1405T>C p.Y469H | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545406; called by muse, mutect2, varscan2
- EEF1AKNMT | c.61T>C p.F21L | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100675916; called by muse, mutect2, varscan2
- ENOX1 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99816251; called by muse, mutect2, varscan2
- EOMES | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV99842044; called by muse, mutect2, varscan2
- EPC2 | c.1626A>T p.E542D | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99309672; called by muse, mutect2, varscan2
- ERAP1 | c.2354T>C p.L785P | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701023; called by muse, mutect2, varscan2
- ERCC2 | c.1378A>G p.T460A | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV101228738; called by muse, mutect2, varscan2
- FAM110A | c.563A>T p.K188M | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99856750; called by muse, mutect2, varscan2
- FBXL16 | c.42C>A p.C14* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100179039; called by muse, mutect2
- FILIP1L | c.2600A>C p.K867T (on ENST00000354552 / NM_182909.3; = p.K627T on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100496973; called by muse, mutect2, varscan2
- FRAS1 | c.9980A>C p.Y3327S | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99352977; called by muse, mutect2, varscan2
- GABRA6 | c.1119G>T p.R373S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.41); catalogued as COSV99194297, COSV99194594; called by muse, mutect2, varscan2
- GDE1 | c.926A>C p.Y309S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99572554; called by muse, mutect2, varscan2
- GPHN | c.263del p.T88Kfs*16 | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | catalogued as COSV100015617; called by mutect2, pindel, varscan2
- HDAC9 | c.1103A>G p.Y368C | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.613); catalogued as rs1374851928, COSV101286820; called by muse, mutect2, varscan2
- HEATR3 | c.139-1G>T p.X47_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99589978; called by muse, mutect2, varscan2
- HEXIM1 | c.145T>A p.S49T | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV100203502; called by muse, mutect2, varscan2
- HIP1R | c.1148A>G p.Q383R | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV99458932; called by muse, mutect2, varscan2
- HMGCR | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV99843305; called by muse, mutect2, varscan2
- IFT172 | c.4870G>T p.D1624Y | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51995233; called by muse, mutect2, varscan2
- IFT80 | c.42A>C p.Q14H | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.212); catalogued as COSV100424838; called by muse, mutect2
- IPO7 | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101121830; called by muse, mutect2, varscan2
- KEAP1 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.339); catalogued as COSV99407898; called by muse, mutect2, varscan2
- KIAA0513 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV50744819; called by muse, mutect2, varscan2
- LGI1 | c.1505A>G p.Y502C | Missense Mutation (SNP) | VAF 299/1595 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101004432; called by muse, mutect2, varscan2
- LRIF1 | c.1853A>C p.E618A | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100870863; called by muse, mutect2, varscan2
- LSR | c.1423C>A p.P475T (on ENST00000361790; = p.P456T on NM_015925.6) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs1178329031, COSV99723422; called by muse, mutect2, varscan2
- MALT1 | c.323A>G p.D108G | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100618759; called by muse, mutect2, varscan2
- MAML2 | c.2260A>G p.M754V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV101594135; called by muse, mutect2
- MAP2K3 | c.172G>T p.E58* (on ENST00000342679 / NM_145109.3; = p.E29* on NM_002756.4) | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | catalogued as COSV100384000; called by muse, mutect2, varscan2
- MAST4 | c.981C>A p.F327L (on ENST00000403625 / NM_001164664.2; = p.F138L on NM_015183.3) | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1182549985, COSV99844534, COSV99845685; called by muse, mutect2
- MATN4 | c.1739C>T p.P580L (on ENST00000372754; = p.P539L on NM_003833.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | PolyPhen benign (0.077); catalogued as rs1374684839, COSV100637064; called by muse, mutect2
- MED13 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV63228574; called by muse, mutect2
- MGME1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100891360; called by muse, mutect2, varscan2
- MIB1 | c.2667C>T p.N889= | Splice Region (SNP) | VAF 22/62 reads (35%) | catalogued as COSV99838924; called by muse, mutect2, varscan2
- MRPL22 | c.102C>G p.H34Q | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV99501709; called by muse, mutect2
- MRPS7 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1337846183, COSV99821629; called by muse, mutect2, varscan2
- MTNR1B | c.260T>A p.L87Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99925162; called by muse, mutect2, varscan2
- MUC16 | c.31985A>T p.D10662V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV101200194; called by muse, mutect2, varscan2
- MVD | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as COSV99964847; called by muse, mutect2
- MYSM1 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101284052; called by muse, mutect2, varscan2
- N4BP1 | c.432A>C p.K144N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99285266; called by muse, mutect2, varscan2
- NIT1 | c.278G>C p.R93P | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.746); catalogued as COSV100919099; called by muse, mutect2, varscan2
- NLRP13 | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs756876652, COSV100738305; called by muse, mutect2, varscan2
- NLRP4 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV100016489; called by muse, mutect2, varscan2
- NOSTRIN | c.1400T>C p.I467T (on ENST00000317647 / NM_001039724.4; = p.I389T on NM_052946.3) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1161662685, COSV100473429; called by muse, mutect2
- NPAP1 | c.2518T>A p.F840I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV100275556, COSV100275819; called by muse, mutect2, varscan2
- NPR3 | c.1057T>A p.Y353N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.02); catalogued as COSV99423211; called by muse, mutect2, varscan2
- NRAS | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV99795232; called by muse, mutect2, varscan2
- NT5M | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV101198605; called by muse, mutect2, varscan2
- NUP153 | c.538A>C p.N180H | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100020442; called by muse, mutect2, varscan2
- ODF1 | c.733T>A p.C245S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV99574256; called by muse, mutect2
- OR8D2 | c.51G>C p.L17F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100659018; called by muse, mutect2, varscan2
- ORC4 | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.981); catalogued as COSV99932295; called by muse, mutect2, varscan2
- PALLD | c.2683C>G p.P895A (on ENST00000505667 / NM_001166108.2; = p.P878A on NM_016081.4) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV99824993; called by muse, mutect2
- PDIA3 | c.1088G>T p.R363I | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV100082606; called by muse, mutect2, varscan2
- PHYHIPL | c.373A>G p.S125G | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100874200; called by muse, mutect2, varscan2
- PIK3C2G | c.2483A>G p.Q828R (on ENST00000676171; = p.Q787R on NM_004570.5) | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.024); catalogued as COSV99852126; called by muse, mutect2, varscan2
- PKHD1 | c.4625A>C p.D1542A | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.574); catalogued as COSV100583446; called by muse, mutect2, varscan2
- PKLR | c.227T>G p.L76R | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100712922, COSV100712937, COSV61360636; called by muse, mutect2, varscan2
- PLCB1 | c.272A>G p.D91G | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100571324; called by muse, mutect2, varscan2
- PLEKHH1 | c.3135C>A p.D1045E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs987704024, COSV100233234; called by muse, mutect2, varscan2
- PPM1G | c.845A>T p.D282V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100085203; called by muse, mutect2
- PRR12 | c.1267G>C p.D423H (on ENST00000615927; = p.D1244H on NM_020719.3) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV101330701; called by muse, mutect2
- PTPRB | c.5449C>A p.P1817T | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99717772; called by muse, mutect2, varscan2
- RANBP2 | c.6260A>G p.H2087R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99312358; called by muse, mutect2, varscan2
- REXO4 | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100905749; called by mutect2, varscan2
- RICTOR | c.4608A>T p.Q1536H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.471); catalogued as COSV99705157; called by muse, mutect2, varscan2
- RNF31 | c.284G>A p.W95* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99396106; called by muse, mutect2, varscan2
- RORA | c.716T>C p.I239T (on ENST00000335670 / NM_134261.3; = p.I264T on NM_002943.3) | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as COSV99832773; called by muse, mutect2, varscan2
- RPF2 | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV100923296; called by muse, mutect2
- RYR2 | c.13150C>A p.L4384M | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs1008031175, COSV63702192; called by muse, mutect2, varscan2
- SACS | c.8331G>T p.R2777S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV101207507; called by muse, mutect2, varscan2
- SCARB2 | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99357969; called by muse, mutect2, varscan2
- SCARB2 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99357972; called by muse, mutect2, varscan2
- SCN9A | c.2267T>G p.L756* (on ENST00000303354; = p.L745* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 30/117 reads (26%) | catalogued as COSV100313126; called by muse, mutect2, varscan2
- SERP1 | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV99526520; called by muse, mutect2, varscan2
- SERPINA10 | c.1126A>C p.N376H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.121); catalogued as COSV100003847; called by muse, mutect2, varscan2
- SF3B3 | c.2398A>T p.I800F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100209979; called by muse, mutect2, varscan2
- SH3YL1 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.845); catalogued as COSV100642167; called by muse, mutect2, varscan2
- SHROOM3 | c.4882C>G p.L1628V | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.098); catalogued as COSV99934568; called by muse, mutect2
- SIPA1L3 | c.3061G>A p.D1021N | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs150829300; called by muse, mutect2, varscan2
- SLC20A1 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99734109; called by muse, mutect2
- SLC27A3 | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV99669981; called by muse, mutect2, varscan2
- SLC2A4 | c.844C>G p.R282G | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV50302746, COSV99142732; called by muse, mutect2, varscan2
- SLC2A5 | c.1174+1G>A p.X392_splice | Splice Site (SNP) | VAF 18/61 reads (30%) | catalogued as rs1485079694, COSV101072663; called by muse, mutect2, varscan2
- SLC34A1 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs1294468517, COSV100183990; called by muse, mutect2
- SLC39A8 | c.323T>G p.L108W | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100765777; called by muse, mutect2, varscan2
- SLC44A1 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101029435; called by muse, mutect2
- SLC6A15 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772986380, COSV99881004; called by muse, mutect2, varscan2
- SMARCE1 | c.817-1G>C p.X273_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99228401; called by muse, varscan2
- SMG9 | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV54213865; called by muse, mutect2, varscan2
- SNRNP40 | c.142-1G>T p.X48_splice | Splice Site (SNP) | VAF 21/98 reads (21%) | catalogued as COSV99745428; called by muse, mutect2, varscan2
- SORL1 | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV99494240; called by muse, mutect2, varscan2
- SPINT1 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.027); catalogued as COSV100689093; called by muse, mutect2, varscan2
- SPIRE1 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100563757; called by muse, mutect2, varscan2
- SPTBN1 | c.3923A>G p.N1308S | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as rs1393785368, COSV100442826; called by muse, mutect2, varscan2
- SPTBN4 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100151187; called by muse, mutect2, varscan2
- STK31 | c.974A>G p.K325R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100669523; called by muse, mutect2, varscan2
- SYT13 | c.169G>T p.G57W | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.186); catalogued as COSV99194736; called by muse, mutect2, varscan2
- SYT14 | c.125T>G p.L42R | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99655457; called by muse, mutect2, varscan2
- TAAR2 | c.781G>T p.A261S (on ENST00000367931 / NM_001033080.1; = p.A216S on NM_014626.3) | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99255652; called by muse, mutect2, varscan2
- TACO1 | c.154T>C p.F52L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99366510; called by muse, mutect2, varscan2
- THBS2 | c.50A>C p.Q17P | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.06); catalogued as COSV100827933; called by muse, mutect2, varscan2
- TIPARP | c.1532A>C p.K511T | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99903859; called by muse, mutect2, varscan2
- TLK1 | c.164T>A p.L55Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100688415; called by muse, mutect2, varscan2
- TLR3 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99711053; called by muse, mutect2, varscan2
- TMC3 | c.1697A>T p.Y566F | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.803); catalogued as COSV100845922; called by muse, mutect2, varscan2
- TMEM255A | c.685A>T p.N229Y | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550419; called by muse, mutect2, varscan2
- TOE1 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517440; called by muse, mutect2, varscan2
- TOGARAM2 | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs757275245, COSV101091197; called by muse, mutect2, varscan2
- TOP1 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.113); catalogued as COSV100793862; called by muse, mutect2, varscan2
- TPTE2 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs1186420189, COSV99690493; called by muse, mutect2, varscan2
- TRIM42 | c.716A>T p.Q239L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV99648454; called by muse, mutect2, varscan2
- TRIM65 | c.188A>C p.N63T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99485496; called by muse, varscan2
- TRIOBP | c.1700C>G p.P567R | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as COSV100730926; called by muse, varscan2
- TTI2 | c.1024G>T p.V342F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100659741; called by muse, mutect2, varscan2
- TXK | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99972517; called by muse, mutect2, varscan2
- UGP2 | c.1456A>C p.I486L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.847); catalogued as COSV99708240; called by muse, mutect2, varscan2
- VIPR1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.226); catalogued as rs947989658, COSV100285656; called by muse, mutect2, varscan2
- VPS8 | c.2524C>T p.L842F (on ENST00000625842 / NM_001349294.1; = p.L840F on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99802527; called by muse, mutect2, varscan2
- VSIG2 | c.835G>C p.G279R | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV99423290; called by muse, mutect2, varscan2
- WDFY3 | c.7708A>T p.M2570L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99883946; called by muse, mutect2, varscan2
- WDR11 | c.1144A>G p.I382V | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs543120664, COSV99676663; called by muse, mutect2, varscan2
- WDR44 | c.1938T>A p.H646Q | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561636; called by muse, mutect2, varscan2
- WFS1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs111773340, COSV99901315; called by muse, mutect2
- ZFPM1 | c.267A>G p.P89= | Splice Region (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100128503; called by muse, mutect2, varscan2
- ZNF329 | c.1418A>T p.H473L | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100798758; called by muse, mutect2, varscan2
- ZNF347 | c.2387G>T p.G796V | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100498329; called by muse, mutect2, varscan2
- ZNF415 | c.228T>A p.H76Q | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.308); catalogued as COSV99701670; called by muse, mutect2, varscan2
- ZNF528 | c.1517C>A p.S506* | Nonsense Mutation (SNP) | VAF 42/150 reads (28%) | catalogued as COSV100846598; called by muse, mutect2, varscan2
- ZNF7 | c.1524G>C p.Q508H | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.25); catalogued as COSV99074217; called by muse, mutect2, varscan2
- ZNF706 | c.109T>G p.L37V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100245425; called by muse, mutect2, varscan2
- ZNF75D | c.321C>A p.N107K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100883659; called by muse, mutect2, varscan2
- ZNF761 | c.1532G>A p.C511Y | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.053); catalogued as COSV100483410; called by muse, mutect2
- ZNRF1 | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100097194; called by muse, mutect2, varscan2
- ANO5 | c.363+1del | Frame Shift Del (DEL) | VAF 70/324 reads (22%) | called by mutect2, pindel, varscan2
- DIAPH3 | c.3266G>T p.R1089L (on ENST00000400324 / NM_001042517.2; = p.R826L on NM_030932.3) | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- FNDC5 | c.549del p.E183Dfs*93 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | called by mutect2, pindel, varscan2
- GRIK1 | c.2483_2485del p.S828_A829delinsT | In Frame Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- HGF | c.1169-34_1171del p.X390_splice | Splice Site (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel
- KLF13 | c.432_437del p.E144_G146delinsD | In Frame Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- LATS1 | c.263_270del p.F88* | Frame Shift Del (DEL) | VAF 11/87 reads (13%) | called by mutect2, pindel, varscan2
- MAN2B2 | c.945_952del p.E315Dfs*104 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- MBOAT7 | c.1349del p.G450Afs*39 | Frame Shift Del (DEL) | VAF 15/126 reads (12%) | called by mutect2, pindel, varscan2
- NLGN1 | c.1304_1306dup p.T435dup | In Frame Ins (INS) | VAF 32/131 reads (24%) | called by mutect2, pindel, varscan2
- SHBG | c.6_18del p.E2Dfs*25 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- SLC30A1 | c.1270_1274dup p.S426* | Nonsense Mutation (INS) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- SPECC1L | c.5del p.K2Rfs*16 | Frame Shift Del (DEL) | VAF 59/223 reads (26%) | called by mutect2, pindel, varscan2
- TMEM121B | c.565_572del p.G189Pfs*43 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel
- UGT2B4 | c.364_367del p.I122Lfs*8 | Frame Shift Del (DEL) | VAF 40/119 reads (34%) | called by mutect2, pindel, varscan2
- UTRN | c.6675_6696del p.S2226Kfs*3 | Frame Shift Del (DEL) | VAF 25/111 reads (23%) | called by mutect2, pindel, varscan2
- ZNF510 | c.1665_1668del p.K556Ifs*114 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- ZNF583 | c.1092_1127del p.G365_G376del | In Frame Del (DEL) | VAF 32/141 reads (23%) | called by mutect2, pindel
- A2M | c.495A>G p.V165= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs1407483466, COSV100588750; called by muse, mutect2, varscan2
- AC004922.1 | c.1236G>A p.T412= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as rs373569413; called by muse, mutect2, varscan2
- AKT3 | c.387A>T p.G129= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99795698; called by muse, mutect2, varscan2
- ANKRD11 | c.3072A>G p.K1024= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99969711; called by muse, mutect2, varscan2
- ARFGEF3 | c.1725T>C p.T575= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV99293821; called by muse, mutect2, varscan2
- ARMCX2 | c.189C>A p.I63= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100168194; called by muse, mutect2, varscan2
- ATP6V1C1 | c.462A>G p.E154= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV101215033; called by muse, mutect2, varscan2
- CCDC116 | c.342A>G p.P114= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99488948; called by muse, mutect2, varscan2
- CSE1L | c.1476A>G p.R492= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99522073; called by muse, mutect2, varscan2
- DAAM2 | c.2730C>A p.V910= (on ENST00000274867 / NM_001201427.2; = p.V909= on NM_015345.3) | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99225959; called by muse, mutect2
- DIDO1 | c.2292T>C p.S764= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV99826182; called by muse, mutect2, varscan2
- DLG1 | c.174G>A p.V58= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV100015481; called by muse, mutect2, varscan2
- DNAH5 | c.12492A>G p.T4164= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs141935657; called by muse, mutect2, varscan2
- DNAI3 | c.573A>G p.E191= | Silent (SNP) | VAF 78/255 reads (31%) | catalogued as COSV99641984; called by muse, mutect2, varscan2
- EIF3A | c.756T>A p.A252= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV100974652; called by muse, mutect2
- EIF4G2 | c.1378C>A p.R460= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs746458672, COSV60596336, COSV60598957; called by muse, mutect2, varscan2
- EIF4G2 | c.309G>A p.V103= | Silent (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- EPRS1 | c.3204C>A p.I1068= | Silent (SNP) | VAF 94/280 reads (34%) | catalogued as COSV100859407, COSV65098928; called by muse, mutect2, varscan2
- ETV7 | c.1011A>T p.P337= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100339222; called by muse, mutect2, varscan2
- FAM189B | c.987G>A p.L329= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV100617457; called by muse, mutect2, varscan2
- FANCD2 | c.967T>C p.L323= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs370641659, COSV99811588; called by muse, mutect2, varscan2
- FIBCD1 | c.774C>T p.Y258= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as COSV99447199; called by muse, mutect2, varscan2
- GLRA3 | c.948T>C p.I316= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV99927672; called by muse, mutect2, varscan2
- GNL2 | c.15G>A p.K5= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100895012; called by muse, mutect2, varscan2
- GSTA4 | c.249C>A p.G83= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV100919856; called by muse, mutect2, varscan2
- HPS5 | c.144T>A p.A48= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100834441; called by muse, mutect2, varscan2
- INF2 | c.3165C>A p.P1055= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV53032876, COSV99383999; called by muse, mutect2, varscan2
- INTS8 | c.2466T>G p.V822= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV100569316; called by muse, mutect2, varscan2
- KCNA1 | c.324G>T p.V108= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV101230290; called by muse, mutect2, varscan2
- KIFC3 | c.2268C>G p.L756= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV101109224; called by muse, mutect2
- KLHL38 | c.282G>A p.T94= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs1253431137, COSV58086809, COSV58088082; called by muse, mutect2, varscan2
- LOXL3 | c.1875T>C p.N625= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as rs751033818, COSV51206119; called by muse, mutect2
- LRIG1 | c.2715A>G p.K905= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99833891; called by muse, mutect2, varscan2
- LRP6 | c.1398A>T p.G466= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV99743541; called by muse, mutect2, varscan2
- MAST2 | c.3228A>T p.P1076= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100788318; called by muse, mutect2, varscan2
- MEP1A | c.810T>C p.T270= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV100042821; called by muse, mutect2, varscan2
- MSLNL | c.387C>T p.A129= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as rs1246341322, COSV99558394; called by muse, mutect2, varscan2
- NRDC | c.1636A>C p.R546= | Silent (SNP) | VAF 116/411 reads (28%) | catalogued as rs1272315498, COSV100703487; called by muse, mutect2, varscan2
- NT5E | c.783G>T p.G261= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100004200; called by muse, mutect2, varscan2
- OR4D9 | c.393C>T p.H131= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100259861; called by muse, mutect2, varscan2
- PCDHA3 | c.498G>A p.S166= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV65366832; called by muse, mutect2, varscan2
- PPP4R2 | c.603G>A p.E201= | Silent (SNP) | VAF 58/224 reads (26%) | catalogued as COSV99866139; called by muse, mutect2, varscan2
- PRR5L | c.639G>A p.L213= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV100287118; called by muse, mutect2, varscan2
- PSMB10 | c.285A>T p.T95= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99863106; called by muse, mutect2, varscan2
- ROPN1L | c.639T>C p.F213= | Silent (SNP) | VAF 93/471 reads (20%) | catalogued as COSV99928683; called by muse, mutect2, varscan2
- RPGRIP1L | c.3714C>G p.T1238= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100046439; called by muse, mutect2, varscan2
- SLC6A13 | c.1614T>C p.A538= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100569983; called by muse, mutect2, varscan2
- SMARCC2 | c.648C>A p.I216= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as COSV99911457; called by muse, mutect2, varscan2
- TADA2A | c.561G>A p.L187= | Silent (SNP) | VAF 30/101 reads (30%) | called by muse, mutect2, varscan2
- TBC1D9 | c.3714C>T p.A1238= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV101464358; called by muse, mutect2, varscan2
- TLR6 | c.2148C>A p.L716= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as COSV101126281; called by muse, mutect2
- TMEM127 | c.132G>A p.L44= | Silent (SNP) | VAF 253/877 reads (29%) | catalogued as COSV99302652; called by muse, mutect2, varscan2
- TMEM143 | c.258A>C p.L86= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV99507346; called by muse, mutect2, varscan2
- TPTE2 | c.132A>G p.R44= | Silent (SNP) | VAF 131/468 reads (28%) | catalogued as rs1208340687, COSV99690489; called by muse, mutect2, varscan2
- TSC22D2 | c.621T>G p.T207= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100721234; called by muse, mutect2, varscan2
- TTN | c.23616T>C p.V7872= (on ENST00000591111; = p.V6945= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as COSV100617698; called by muse, mutect2, varscan2
- UNC5D | c.1293A>T p.T431= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99776085; called by muse, mutect2, varscan2
- WDR82 | c.216T>A p.T72= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV99626882; called by muse, mutect2, varscan2
- ZNF573 | c.1443T>C p.T481= (on ENST00000536220 / NM_001172692.1; = p.T423= on NM_152360.3) | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as rs1417989682, COSV100265677; called by muse, mutect2, varscan2
- ZNF615 | c.1716A>G p.E572= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100943855; called by muse, mutect2, varscan2
- ZNF766 | c.933T>C p.S311= | Silent (SNP) | VAF 33/162 reads (20%) | catalogued as COSV100765369; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2656_2462-2653del | Intron (DEL) | VAF 37/125 reads (30%) | called by mutect2, pindel, varscan2
- FAM184A | c.3342-652T>C | Intron (SNP) | VAF 94/286 reads (33%) | called by muse, mutect2, varscan2
- FGFR2 | c.939+1233_940-1255delinsTT | Intron (DEL) | VAF 13/64 reads (20%) | called by pindel, varscan2*
- MAP2 | c.4585-964A>G | Intron (SNP) | VAF 32/341 reads (9%) | catalogued as COSV99560459; called by muse, mutect2
- MIR20A | n.39T>C | RNA (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- NACA | c.71-2340G>A | Intron (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100771395; called by muse, mutect2, varscan2
- PDXK | c.88-1655A>C | Intron (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99376438; called by muse, mutect2, varscan2
- PMF1 | c.162-6697A>G | Intron (SNP) | VAF 50/144 reads (35%) | catalogued as rs1285607892, COSV100196210; called by muse, mutect2, varscan2
- SLC48A1 | c.*106G>A | 3'UTR (SNP) | VAF 17/92 reads (18%) | catalogued as COSV99316377; called by muse, mutect2, varscan2
